Somatic mutation profile of tumor specimen TCGA-IB-7652-01A (aliquot TCGA-IB-7652-01A-11D-2154-08) from TCGA case TCGA-IB-7652, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 49.6 years (18,129 days).
Specimen TCGA-IB-7652-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98eafe13-2484-4316-88ca-a50a4d33d3cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7652-10A (Blood Derived Normal), aliquot TCGA-IB-7652-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5af0a410-30e3-49b4-bc61-c99a0be88bdf

The open-access MAF lists 97 somatic variants for this specimen: 77 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 63, Silent 20, Frame Shift Del 5, Nonsense Mutation 4, In Frame Del 3, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 54/233 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTSL2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478392567, COSV63203838; called by muse, mutect2, varscan2
- AK7 | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 83/588 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV99966898; called by muse, mutect2, varscan2
- AKAP6 | c.4775G>A p.R1592Q | Missense Mutation (SNP) | VAF 135/695 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776536609, COSV99797485; called by muse, mutect2, varscan2
- CACNA1A | c.2694G>T p.E898D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.21); catalogued as COSV64214537; called by muse, mutect2, varscan2
- CACNG3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 71/695 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770078893, COSV50068830; called by muse, mutect2, varscan2
- CCDC81 | c.1786C>T p.Q596* (on ENST00000445632 / NM_001156474.2; = p.Q506* on NM_021827.4) | Nonsense Mutation (SNP) | VAF 68/370 reads (18%) | catalogued as COSV99563790; called by muse, mutect2, varscan2
- CCSER2 | c.1109A>T p.N370I | Missense Mutation (SNP) | VAF 115/534 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99825333; called by muse, mutect2, varscan2
- CCT8L2 | c.380T>A p.L127Q | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100742507; called by muse, mutect2, varscan2
- CECR2 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs767550931, COSV99376756; called by muse, mutect2, varscan2
- CFAP47 | c.2150G>A p.R717K | Missense Mutation (SNP) | VAF 75/432 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99934105; called by muse, mutect2, varscan2
- CIP2A | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99842562; called by muse, mutect2, varscan2
- COL5A3 | c.3910G>A p.G1304S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751999757, COSV53412780; called by muse, mutect2
- CXorf21 | c.341C>A p.P114Q | Missense Mutation (SNP) | VAF 156/880 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100973202; called by muse, mutect2, varscan2
- DAAM1 | c.482T>G p.I161S | Missense Mutation (SNP) | VAF 108/647 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1482161359, COSV100658049; called by muse, mutect2, varscan2
- DAB2IP | c.2904G>T p.R968S (on ENST00000408936; = p.R940S on NM_032552.3) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as COSV99404471; called by muse, mutect2, varscan2
- DDX31 | c.2291G>C p.R764T | Missense Mutation (SNP) | VAF 136/797 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100936552; called by muse, mutect2, varscan2
- DMD | c.10061A>T p.Y3354F | Missense Mutation (SNP) | VAF 18/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100625566; called by muse, mutect2
- DNAH17 | c.8968T>C p.F2990L | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV101101103; called by muse, mutect2, varscan2
- DNAJC13 | c.3561G>T p.K1187N | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV99606339; called by muse, mutect2
- E2F3 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 163/950 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs1330116976, COSV100685646, COSV60898676; called by muse, mutect2, varscan2
- EGR1 | c.1615A>G p.T539A | Missense Mutation (SNP) | VAF 82/608 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV99525218; called by muse, mutect2, varscan2
- ERO1A | c.1370T>A p.L457* | Nonsense Mutation (SNP) | VAF 5/55 reads (9%) | catalogued as COSV101193558; called by muse, mutect2
- FAT2 | c.6746C>A p.A2249D | Missense Mutation (SNP) | VAF 110/666 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99941352; called by muse, mutect2, varscan2
- FLNB | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 132/729 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV99911329; called by muse, mutect2, varscan2
- FLNB | c.5856T>A p.C1952* | Nonsense Mutation (SNP) | VAF 12/141 reads (9%) | catalogued as COSV99911334; called by muse, mutect2
- FLNC | c.1323A>T p.R441S | Missense Mutation (SNP) | VAF 106/749 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as COSV100367512; called by muse, mutect2, varscan2
- FLT4 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV56101712; called by muse, mutect2, varscan2
- FMO1 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 82/432 reads (19%) | catalogued as rs868481272, COSV61446482; called by muse, mutect2, varscan2
- GALR1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV55315761, COSV99077564; called by muse, mutect2, varscan2
- GDF11 | c.787G>C p.D263H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99143952; called by muse, mutect2, varscan2
- GPR83 | c.247G>T p.V83F | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV99703500; called by muse, mutect2, varscan2
- GRSF1 | c.1318A>G p.T440A | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs964674991, COSV99635429; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.502); catalogued as COSV100441034; called by muse, mutect2, varscan2
- HECW2 | c.396G>C p.M132I | Missense Mutation (SNP) | VAF 85/1220 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99645437; called by muse, mutect2
- HOMER2 | c.453G>T p.K151N (on ENST00000304231 / NM_199330.3; = p.K140N on NM_004839.4) | Missense Mutation (SNP) | VAF 140/891 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV100420134; called by muse, mutect2, varscan2
- IGSF1 | c.3214C>G p.Q1072E | Missense Mutation (SNP) | VAF 169/1173 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV100811762, COSV63836795; called by muse, mutect2, varscan2
- KCNA2 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 162/996 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV100315778; called by muse, mutect2, varscan2
- LRP1B | c.4107A>T p.R1369S | Missense Mutation (SNP) | VAF 113/685 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101250260; called by muse, mutect2, varscan2
- LRRK1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 102/687 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs368091026; called by muse, mutect2, varscan2
- MROH9 | c.1696G>T p.G566C | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV100882643; called by muse, mutect2, varscan2
- MROH9 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 40/334 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.157); catalogued as COSV100882644; called by muse, mutect2, varscan2
- NOBOX | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 74/384 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376334807, COSV99779093; called by muse, mutect2, varscan2
- NTF3 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV58417437, COSV58418416; called by muse, mutect2, varscan2
- OR10A6 | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs763830443, COSV100564224; called by muse, mutect2, varscan2
- OR12D2 | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 164/957 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.436); catalogued as COSV101011059, COSV65829259; called by muse, mutect2, varscan2
- OR13F1 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 86/1361 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs1351489232, COSV100594659, COSV100594880; called by muse, mutect2
- OR1K1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 111/342 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs748623617, COSV52956973; called by muse, mutect2, varscan2
- OR2T8 | c.347T>A p.M116K | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100177975; called by muse, mutect2, varscan2
- PC | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV63081920, COSV63083371; called by muse, mutect2, varscan2
- PCDH10 | c.1576T>G p.Y526D | Missense Mutation (SNP) | VAF 83/508 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99992691; called by muse, mutect2, varscan2
- PCDH11X | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 74/528 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.13); catalogued as rs761488640, COSV53438348; called by muse, mutect2, varscan2
- PCDHA4 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 71/524 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV63542477; called by muse, mutect2, varscan2
- PCDHA7 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 90/606 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.116); catalogued as COSV65344853; called by muse, mutect2, varscan2
- PCNX2 | c.1337C>G p.P446R | Missense Mutation (SNP) | VAF 108/499 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.05); catalogued as COSV99265556; called by muse, mutect2, varscan2
- PDS5B | c.1054A>T p.T352S | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); catalogued as COSV100220327; called by muse, mutect2, varscan2
- PRAMEF19 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 311/2186 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs754660509, COSV65819448; called by muse, mutect2, varscan2
- PRKN | c.21C>A p.F7L | Missense Mutation (SNP) | VAF 20/353 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV100626915; called by muse, mutect2
- PRSS35 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 109/549 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766090161, COSV100864006; called by muse, mutect2, varscan2
- RAB39A | c.443A>T p.D148V | Missense Mutation (SNP) | VAF 89/511 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.033); catalogued as rs1438484630, COSV100269037, COSV57695682; called by muse, mutect2, varscan2
- SLCO6A1 | c.1517G>A p.C506Y | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV65808346, COSV65814744; called by muse, mutect2, varscan2
- TAS2R42 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 86/487 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1176467170, COSV62085070; called by muse, mutect2, varscan2
- TERT | c.3362C>A p.P1121Q | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99715726, COSV99716514; called by muse, mutect2, varscan2
- U2SURP | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101204302; called by muse, mutect2, varscan2
- VPS13D | c.724G>C p.V242L | Missense Mutation (SNP) | VAF 307/996 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV100692028; called by muse, mutect2, varscan2
- ZEB1 | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 65/349 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.158); catalogued as COSV100313479; called by muse, mutect2, varscan2
- ZFYVE9 | c.2746+2T>C p.X916_splice | Splice Site (SNP) | VAF 86/506 reads (17%) | catalogued as COSV99819216; called by muse, mutect2, varscan2
- ZNF521 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs976556591, COSV64128150; called by muse, mutect2
- ARCN1 | c.21_58del p.T10Gfs*8 | Frame Shift Del (DEL) | VAF 89/764 reads (12%) | called by mutect2, pindel
- ATR | c.3983_4020del p.V1328Efs*35 | Frame Shift Del (DEL) | VAF 60/526 reads (11%) | called by mutect2, pindel
- CACNA2D3 | c.2633_2634del p.F878Wfs*2 | Frame Shift Del (DEL) | VAF 24/168 reads (14%) | called by pindel, varscan2*
- DOCK11 | c.2735_2745del p.L912Hfs*4 | Frame Shift Del (DEL) | VAF 94/721 reads (13%) | called by mutect2, pindel, varscan2
- E4F1 | c.1384_1401del p.P462_Q467del | In Frame Del (DEL) | VAF 22/165 reads (13%) | called by mutect2, pindel
- FLG | c.10377_10388del p.S3460_H3463del | In Frame Del (DEL) | VAF 211/2353 reads (9%) | called by mutect2, pindel
- KMT2C | c.13674dup p.G4559Wfs*15 | Frame Shift Ins (INS) | VAF 58/387 reads (15%) | called by mutect2, pindel, varscan2
- PDZD2 | c.6049_6078del p.P2017_G2026del | In Frame Del (DEL) | VAF 144/1487 reads (10%) | called by mutect2, pindel
- RASSF2 | c.542_560del p.S181Lfs*13 | Frame Shift Del (DEL) | VAF 24/271 reads (9%) | called by mutect2, pindel
- A4GNT | c.135C>G p.L45= | Silent (SNP) | VAF 69/426 reads (16%) | catalogued as rs757833434, COSV52628550, COSV99367657; called by muse, mutect2, varscan2
- AC244197.3 | c.9G>T p.T3= | Silent (SNP) | VAF 24/720 reads (3%) | catalogued as COSV100557779, COSV61714275; called by muse, mutect2
- ARHGEF37 | c.1170C>T p.A390= | Silent (SNP) | VAF 40/482 reads (8%) | catalogued as rs772671320, COSV100381841; called by muse, mutect2
- ASPM | c.6999G>A p.E2333= | Silent (SNP) | VAF 119/701 reads (17%) | catalogued as COSV99659285; called by muse, mutect2, varscan2
- FSTL4 | c.1953C>T p.H651= | Silent (SNP) | VAF 40/192 reads (21%) | catalogued as COSV99530952; called by muse, mutect2, varscan2
- HCK | c.405C>T p.R135= | Silent (SNP) | VAF 100/616 reads (16%) | catalogued as rs913095249, COSV52941773; called by muse, mutect2, varscan2
- ITK | c.111C>T p.S37= | Silent (SNP) | VAF 137/823 reads (17%) | catalogued as COSV101439552; called by muse, mutect2, varscan2
- KCNT1 | c.2841C>T p.A947= (on ENST00000488444; = p.A966= on NM_020822.3) | Silent (SNP) | VAF 44/435 reads (10%) | catalogued as rs762968242, COSV53696184; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIAA1217 | c.1404C>A p.S468= | Silent (SNP) | VAF 81/441 reads (18%) | catalogued as COSV100286016; called by muse, mutect2, varscan2
- MTM1 | c.1257A>C p.A419= | Silent (SNP) | VAF 52/329 reads (16%) | catalogued as COSV100080102; called by muse, mutect2, varscan2
- MYOZ1 | c.45C>T p.S15= | Silent (SNP) | VAF 84/451 reads (19%) | catalogued as COSV100831749; called by muse, mutect2, varscan2
- OR9G1 | c.201T>C p.F67= | Silent (SNP) | VAF 76/712 reads (11%) | catalogued as COSV100380196; called by muse, mutect2, varscan2
- PDS5B | c.3246A>G p.T1082= | Silent (SNP) | VAF 127/727 reads (17%) | catalogued as rs774532596, COSV100220329; called by muse, mutect2, varscan2
- PPEF1 | c.1761C>T p.S587= | Silent (SNP) | VAF 116/579 reads (20%) | catalogued as rs1187927797, COSV100583473; called by muse, mutect2, varscan2
- PTGS1 | c.273G>T p.L91= | Silent (SNP) | VAF 119/709 reads (17%) | catalogued as COSV99792818; called by muse, mutect2, varscan2
- PTPN13 | c.4011A>T p.P1337= (on ENST00000411767 / NM_080683.3; = p.P1318= on NM_006264.3) | Silent (SNP) | VAF 98/581 reads (17%) | catalogued as COSV100363858; called by muse, mutect2, varscan2
- SCN1A | c.5346C>T p.I1782= (on ENST00000303395 / NM_001202435.3; = p.I1771= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 196/1159 reads (17%) | catalogued as rs121918763, CM096172, COSV57668747; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SEMA6B | c.528C>T p.Y176= | Silent (SNP) | VAF 41/245 reads (17%) | catalogued as rs1413012110, COSV56706534; called by muse, mutect2, varscan2
- TBP | c.276G>A p.Q92= | Silent (SNP) | VAF 88/386 reads (23%) | catalogued as rs796895015; called by muse, varscan2
- TCEAL5 | c.252A>T p.P84= | Silent (SNP) | VAF 164/992 reads (17%) | catalogued as COSV101013080; called by muse, mutect2, varscan2
